CGCI case BLGSP-71-30-00779 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/985774ca-6c12-4449-a2ea-ffd84b18e8ed

Demographics
Sex at birth: male; Age at index: 52 years; Vital status: Alive.

Diagnoses (1)
1. B-cell lymphoma, unclassifiable, with features intermediate between diffuse large B-cell lymphoma and Burkitt lymphoma: ICD-O-3 morphology code: 9680/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 52.9 years (19,321 days); Year of diagnosis: 2012; Method of diagnosis: Incisional Biopsy; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 3,170 days (8.7 years); Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Mesenteric lymph nodes; Sites of involvement: Small intestine / Transplanted kidney.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Mesenteric; Lymph nodes positive: 1; Lymph nodes tested: 1; Tumor largest dimension diameter: 2 cm.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: CVP-R; Days to treatment start: 3 days; Days to treatment end: 92 days; Number of cycles: 4; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: CODOX-R; Days to treatment start: 3 days; Days to treatment end: 92 days; Number of cycles: 4; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: IVAC-R; Days to treatment start: 3 days; Days to treatment end: 92 days; Number of cycles: 4; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Cytarabine + Doxorubicin + Etoposide + Ifosfamide + Prednisone + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 3 days; Days to treatment end: 92 days; Number of cycles: 4; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 0 days; ECOG performance status: 3.
- Days to follow up: 3,170 days (8.7 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 2,411.

Molecular and laboratory tests
- BCL2 (FISH): Normal.
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- FMC-7 (IHC): Positive; Specialized molecular test: FMC-7.
- FOXP1 (IHC): Positive.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC other (FISH): Abnormal, NOS.
- MYC translocation (FISH): Abnormal, NOS.
- Epstein-Barr Virus (ISH): Negative.
- Lactate Dehydrogenase 1177 [Blood test normal range upper: 240].

Other clinical attributes
- Day 0: Weight: 92.7 kg; Height: 168 cm; BMI: 32.8.
- Day 0: Comorbidities: Organ Transplant (Site).
- Day 0: Immunosuppressive treatment type: Other; Risk factor treatment: Yes.

Biospecimens (2 samples)
- Sample BLGSP-71-30-00779-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
- Sample BLGSP-71-30-00779-01Z: Sample type: Tumor; Tissue type: Tumor.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: History immunological disease other: kidney transplant; History immunosuppressive prescription other: Tacrolimus.
- Primary pathology: Histologic diagnosis: B-cell lymphoma (unclassifiable) with features intermediate between DLBCL and Burkitt lymphoma; Extranodal site involvement: 2; Extranodal involvment other: transplanted kidney; Lymph nodes examined: Yes; Lymph nodes examined IHC count: 0.
- Primary pathology, Pos lymph node locations: Pos lymph node location: Other Location, specify.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 1177; Immunophenotypic analysis method: Immunohistochemistry; Ebv status malignan cells method: EBER in situ hybridization.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: FMC7.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunophenotypic analysis tested: FOXP1.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 1: Genetic abnormality tested: C-myc.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 2: Genetic abnormality tested: BCL2.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 3: Genetic abnormality tested: MYC.
- Follow-up form 1: Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Treatments, Treatment: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: CVP-R (modified)/IVACR, CODOXR/IVACR; Pharma adjuvant cycles count: 4.

Additional fields from the CGCI biospecimen supplement workbook CGCI-BLGSP_biospecimenSupplementSpreadsheet_TWIST_20220304.xlsx (sheet Sheet1), for sample BLGSP-71-30-00779-01A-01E-0001-01:
- % tumour: 95
